Somatic mutation profile of tumor specimen MP2PRT-PARGZE-TMP1-A (aliquot MP2PRT-PARGZE-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARGZE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,772 days).
Specimen MP2PRT-PARGZE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a19d3194-375c-4adf-a2be-7eb3a1e613e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGZE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGZE-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6f39714-d3f5-4550-975a-ab12fd6f927c

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNB2 | c.731G>A p.R244H (on ENST00000324631 / NM_201596.3; = p.R189H on NM_000724.4) | Missense Mutation (SNP) | VAF 98/565 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1291633086, COSV56640459; called by muse, mutect2, varscan2
- HCRTR2 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 128/448 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.135); catalogued as COSV63793406, COSV63793997; called by muse, mutect2, varscan2
- KLF8 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 175/703 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63848630; called by muse, mutect2, varscan2
- NRG3 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 66/478 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100932801, COSV64574651; called by muse, mutect2, varscan2
- OR52N4 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 44/403 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs753229074; called by muse, mutect2, varscan2
- PCDHB1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554267169, COSV60630142; called by muse, mutect2
- PPP2R3A | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 86/338 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV99386790; called by muse, mutect2, varscan2
- RELN | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373089551, COSV59027537; called by muse, mutect2, varscan2
- SPIRE2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 134/375 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs557283133, COSV65557979; called by muse, mutect2, varscan2
- TTC13 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 33/196 reads (17%) | catalogued as rs756578568, COSV64168962; called by muse, mutect2, varscan2
- USP36 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 137/307 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs866645554; called by muse, mutect2, varscan2
- AOC1 | c.449T>G p.L150R | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ERC2 | c.1310A>G p.D437G | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- GAK | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 104/591 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); called by muse, mutect2
- GLIPR1L2 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HBP1 | c.1391_1392insGGGTT p.I464Mfs*3 | Frame Shift Ins (INS) | VAF 16/194 reads (8%) | called by mutect2, pindel
- MALRD1 | c.5478G>A p.K1826= | Splice Region (SNP) | VAF 18/253 reads (7%) | called by muse, mutect2
- CDH23 | c.8214T>C p.P2738= | Silent (SNP) | VAF 91/665 reads (14%) | called by muse, mutect2, varscan2
- GPR78 | c.228C>T p.P76= | Silent (SNP) | VAF 70/1148 reads (6%) | catalogued as rs1320059794, COSV66763633; called by muse, mutect2
- MRC2 | c.1959G>A p.T653= | Silent (SNP) | VAF 125/664 reads (19%) | catalogued as rs772417411, COSV100316919, COSV57641316; called by muse, mutect2, varscan2
- MTG2 | c.924C>T p.F308= | Silent (SNP) | VAF 79/448 reads (18%) | catalogued as rs778642978, COSV63693501, COSV63694275; called by muse, mutect2, varscan2
- MYO18B | c.6891C>T p.D2297= | Silent (SNP) | VAF 54/462 reads (12%) | catalogued as rs374327917; called by muse, mutect2, varscan2
- RYR3 | c.12624C>T p.I4208= (on ENST00000389232; = p.I4209= on NM_001036.6) | Silent (SNP) | VAF 103/395 reads (26%) | catalogued as COSV66776245, COSV66781360; called by muse, mutect2, varscan2
- TTN | c.10360+2487C>T | Intron (SNP) | VAF 38/291 reads (13%) | catalogued as rs533540386, COSV59960845; called by muse, mutect2, varscan2
